Gene-level copy-number profile of tumor specimen C3L-03726-03 from CPTAC case C3L-03726, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.4 years (28,285 days).
Specimen C3L-03726-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0d7bbf59-e2d1-4a2a-9601-b7c3e3708dd0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03726-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/ebce3a1b-2c8e-494b-ae42-5d0b9b5ad013

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 12,813; copy number 3: 9,270; copy number 4: 28,596; copy number 5: 1,552; copy number 6: 5,617; copy number 7: 122; copy number 8: 54; copy number 9: 292; copy number 10: 31; copy number 12: 41; copy number 16: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 373 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:105,919–206,392, 6 genes, copy number 10: OR4F1P, CICP18, AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr6:391,752–8,760,447, 164 genes, copy number 9 (broad region; genes not listed).
- chr6:8,653,558–8,653,797, 1 gene, copy number 9: AL161437.1.
- chr6:50,587,607–57,856,468, 115 genes, copy number 9 (broad region; genes not listed).
- chr12:12,310–38,133, 3 genes, copy number 9: DDX11L8, WASH8P, FAM138D.
- chr17:142,789–721,717, 16 genes, copy number 9–16: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17.
- chr17:2,017,716–2,303,785, 17 genes, copy number 10 (within-gene range 6–10): AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1, SMG6, AC090617.9, AC090617.4, AC090617.6, AC090617.8, AC090617.7, MCUR1P1.
- chr20:53,137,293–53,141,169, 1 gene, copy number 9: AL391097.3.
- chr20:53,196,229–53,827,297, 9 genes, copy number 9–16: AL391097.2, AL354993.1, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1.
- chr20:63,166,797–63,832,038, 41 genes, copy number 12: AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
